Somatic mutation profile of tumor specimen MMRF_1790_4_BM_CD138pos (aliquot MMRF_1790_4_BM_CD138pos_T1_KHS5U_L16587) from MMRF case MMRF_1790, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.8 years (28,045 days).
Specimen MMRF_1790_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 397d33bc-ddbb-42ab-a597-b2928c10ee62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1790_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1790_1_PB_WBC_C3_KBS5U_L07232; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75e36410-1106-47fb-bd79-7ee9120eeaa0

The open-access MAF lists 122 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 32, Silent 14, Intron 9, 5'UTR 7, 3'Flank 6, Splice Site 4, 5'Flank 3, RNA 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.173C>T p.T58I (on ENST00000377970; = p.T73I on NM_002467.6) | Missense Mutation (SNP) | VAF 147/235 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756091827, COSV52367994, COSV52373588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL7B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs139165156; called by muse, mutect2, varscan2
- ADAT3 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs758520906; called by muse, mutect2, varscan2
- ANXA1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99973838; called by muse, mutect2, varscan2
- CIAPIN1 | c.539A>G p.K180R | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1408790486; called by muse, mutect2, varscan2
- DHRS4L2 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs772988441; called by muse, mutect2
- DLX4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 63/388 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53591923; called by muse, mutect2, varscan2
- DNAI3 | c.446T>G p.V149G | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1409802552; called by muse, mutect2, varscan2
- DNASE1L1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs782288295; called by muse, mutect2, varscan2
- DPP6 | c.692G>A p.S231N (on ENST00000377770 / NM_001364500.2; = p.S169N on NM_001936.5) | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs538699484; called by muse, mutect2
- EGF | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768471434; called by muse, mutect2, varscan2
- ESPL1 | c.4844C>T p.A1615V | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs778039130; called by muse, mutect2, varscan2
- FRAS1 | c.4951C>T p.R1651* | Nonsense Mutation (SNP) | VAF 24/41 reads (59%) | catalogued as rs753960106, COSV99347169, COSV99347494; called by muse, mutect2, varscan2
- IRF4 | c.296G>C p.C99S | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66705766; called by muse, mutect2, varscan2
- ITFG1 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV100278612; called by muse, mutect2, varscan2
- KCNB1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1338339252, COSV65568401; called by muse, mutect2, varscan2
- LINGO2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs781520934, COSV58057149; called by muse, mutect2, varscan2
- PRRT4 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs867388733; called by muse, mutect2, varscan2
- REXO5 | c.561G>C p.L187F | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV54472571; called by muse, mutect2, varscan2
- AL645922.1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALAS2 | c.1434C>G p.I478M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD35 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- API5 | c.1127+1G>T p.X376_splice | Splice Site (SNP) | VAF 26/152 reads (17%) | called by muse, mutect2, varscan2
- ASTN2 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2
- BSPH1 | c.260T>G p.F87C | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C15orf39 | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CLCNKA | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CNKSR2 | c.1831-1G>T p.X611_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- CNKSR2 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DAAM1 | c.3180T>G p.I1060M | Missense Mutation (SNP) | VAF 116/251 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- DNAH10 | c.1114G>C p.E372Q (on ENST00000409039; = p.E311Q on NM_207437.3) | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ECPAS | c.1266-1G>A p.X422_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- EDNRA | c.207C>G p.C69W | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSD11B1 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- HSPB2 | c.64A>C p.S22R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- HUWE1 | c.2261+1G>A p.X754_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- IFNAR1 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHD1-7 | c.5T>G p.I2R | Missense Mutation (SNP) | VAF 33/33 reads (100%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRAG1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- KCNN2 | c.1105T>G p.Y369D (on ENST00000264773; = p.Y581D on NM_021614.4) | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MXRA5 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NPC1 | c.3196A>C p.T1066P | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NYNRIN | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKD2 | c.1688G>C p.G563A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTX4 | c.887C>T p.A296V (on ENST00000447419 / NM_001328608.2; = p.A291V on NM_001013658.1) | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- RBL1 | c.247A>C p.N83H | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF10 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLU7 | c.1396T>A p.S466T | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPTE | c.1586C>T p.S529L (on ENST00000618007 / NM_199261.4; = p.S511L on NM_199259.4) | Missense Mutation (SNP) | VAF 174/905 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- AC099489.1 | c.3273G>T p.R1091= | Silent (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.2340C>T p.G780= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- CLCN6 | c.1920C>T p.R640= | Silent (SNP) | VAF 77/156 reads (49%) | catalogued as rs142493749; called by muse, mutect2, varscan2
- EGR2 | c.579C>A p.T193= | Silent (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- FECH | c.186G>A p.P62= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs550820935, COSV100023356, COSV50490537; called by muse, mutect2, varscan2
- GTF3C1 | c.5808T>C p.S1936= | Silent (SNP) | VAF 135/297 reads (45%) | called by muse, varscan2
- MACF1 | c.10332A>G p.Q3444= | Silent (SNP) | VAF 67/174 reads (39%) | called by muse, mutect2, varscan2
- MAGEH1 | c.513G>C p.S171= | Silent (SNP) | VAF 80/176 reads (45%) | catalogued as rs1477245374; called by muse, mutect2, varscan2
- NPAP1 | c.120T>G p.S40= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs907181578; called by muse, mutect2, varscan2
- NR1D1 | c.981C>G p.T327= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- NSMCE3 | c.222C>T p.A74= | Silent (SNP) | VAF 81/168 reads (48%) | called by muse, mutect2, varscan2
- SLFN12L | c.1545G>C p.S515= (on ENST00000260908 / NM_001363830.1; = p.S533= on NM_001195790.1) | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as rs750552108, COSV53471218, COSV99610120; called by muse, mutect2
- SNTN | c.318C>A p.I106= | Silent (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- UNC80 | c.2874C>T p.A958= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs756648889; called by muse, varscan2
- APEX2 | c.*1237A>G | 3'UTR (SNP) | VAF 58/89 reads (65%) | called by muse, mutect2
- APOBEC4 | c.*420G>A | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, varscan2
- ARMC10P1 | n.791C>G | RNA (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- ATF4 | c.-92del | 5'UTR (DEL) | VAF 16/40 reads (40%) | called by pindel, varscan2
- BCL7A | chr12:122021118 C>T | 5'Flank (SNP) | VAF 90/188 reads (48%) | catalogued as COSV55851758; called by muse, mutect2, varscan2
- CADM1 | c.*6789del | 3'UTR (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- CBLB | c.*14A>T | 3'UTR (SNP) | VAF 24/136 reads (18%) | called by muse, mutect2, varscan2
- CCNL1 | chr3:157160676 C>A | 5'Flank (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- CDH12 | c.*364A>T | 3'UTR (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- CNIH2 | c.*189C>A | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- CUBN | c.*460C>A | 3'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- CYP2A7P2 | n.494C>T | RNA (SNP) | VAF 56/110 reads (51%) | called by muse, mutect2, varscan2
- DNAJA4 | c.-11G>C | 5'UTR (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- ELP3 | c.*653T>G | 3'UTR (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2
- ENTPD7 | c.*612A>G | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13894071 ins G | 3'Flank (INS) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- FAM107A | c.*2012G>C | 3'UTR (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- GNRH1 | c.-502A>T | 5'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- GPR158 | c.-193G>T | 5'UTR (SNP) | VAF 83/173 reads (48%) | catalogued as rs772745398; called by muse, mutect2, varscan2
- H2BC21 | c.*166G>A | 3'UTR (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- HAUS3 | c.*655A>C | 3'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- HS3ST1 | c.*1286G>A | 3'UTR (SNP) | VAF 25/71 reads (35%) | catalogued as rs1440186295; called by muse, mutect2, varscan2
- HYAL2 | c.1012-54C>T | Intron (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- KRTAP19-5 | c.*143C>T | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- MACC1 | chr7:20137538 C>T | 3'Flank (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- MBNL3 | chrX:132377884 A>T | 3'Flank (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- MDGA2 | c.*1329G>A | 3'UTR (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- MFN2 | c.2069+17G>T | Intron (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- NLGN4X | c.*549G>A | 3'UTR (SNP) | VAF 32/68 reads (47%) | catalogued as rs935052626; called by muse, mutect2, varscan2
- NTRK2 | c.1397-56567G>A | Intron (SNP) | VAF 44/104 reads (42%) | catalogued as rs201221612, COSV52857899; called by muse, mutect2, varscan2
- OPN4 | c.-146C>T | 5'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as rs781573936; called by muse, mutect2
- PKN2 | c.*2654A>T | 3'UTR (SNP) | VAF 5/75 reads (7%) | catalogued as rs1179817281; called by muse, mutect2
- PLSCR4 | c.*1567A>T | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- PPP1R42 | c.*100C>A | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- PRKCB | c.1864-2039G>T | Intron (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- RAB40C | c.*128C>T | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- RBSN | c.*2985A>T | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- RNF2 | c.*542C>G | 3'UTR (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- RNF213 | c.10304-136G>T | Intron (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- RNU6-1224P | chr8:102529481 G>C | 3'Flank (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- SEL1L | c.*2717_*2718insC | 3'UTR (INS) | VAF 22/53 reads (42%) | called by pindel, varscan2
- SEL1L | c.*2685T>G | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, varscan2
- SELENOM | c.129+70G>A | Intron (SNP) | VAF 5/25 reads (20%) | called by mutect2, varscan2
- SERP2 | c.158-6717T>C | Intron (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- SESTD1 | c.*4815A>G | 3'UTR (SNP) | VAF 101/194 reads (52%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*2959G>A | 3'UTR (SNP) | VAF 30/62 reads (48%) | catalogued as rs1303542165; called by muse, mutect2, varscan2
- SHANK3 | c.2009-46C>T | Intron (SNP) | VAF 15/32 reads (47%) | catalogued as rs767314767; called by muse, mutect2, varscan2
- SIM1 | c.*537T>C | 3'UTR (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- SLC38A2 | c.117-115A>G | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627493 A>C | 3'Flank (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- SSC4D | c.*662G>C | 3'UTR (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- STK16 | c.*912T>C | 3'UTR (SNP) | VAF 69/134 reads (51%) | called by muse, mutect2, varscan2
- SV2A | c.-138dup | 5'UTR (INS) | VAF 12/44 reads (27%) | catalogued as rs1365759790; called by mutect2, varscan2
- TBX18 | c.*21A>G | 3'UTR (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100858428; called by muse, mutect2, varscan2
- TDO2 | c.*258A>T | 3'UTR (SNP) | VAF 45/87 reads (52%) | called by muse, mutect2, varscan2
- TRIM69 | c.-102C>G | 5'UTR (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- VANGL1 | chr1:115695165 A>T | 3'Flank (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- WDFY3 | c.*218G>C | 3'UTR (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- ZNF503 | chr10:75401827 C>A | 5'Flank (SNP) | VAF 37/133 reads (28%) | called by muse, mutect2, varscan2
